Somatic mutation profile of tumor specimen TCGA-W2-A7HC-01A (aliquot TCGA-W2-A7HC-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 68.0 years (24,834 days).
Specimen TCGA-W2-A7HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb9b43d-b66f-4cd4-9654-81c2a6005ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HC-10C (Blood Derived Normal), aliquot TCGA-W2-A7HC-10C-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcc1cda3-f30a-4e3e-ae7b-1c10f0a8e461

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BARD1 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782662, COSV53612542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF3C1 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315638129; called by muse, mutect2, varscan2
- MATN4 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | PolyPhen possibly damaging (0.532); catalogued as rs918268552, COSV59212726; called by muse, mutect2, varscan2
- ALPK1 | c.3547A>T p.T1183S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FCAR | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.01); called by muse, mutect2
- LPA | c.3967T>A p.C1323S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NXT2 | c.242T>C p.V81A (on ENST00000372106 / NM_001242617.2; = p.V136A on NM_018698.5) | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR7C2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PKD1L1 | c.4201G>T p.A1401S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RNF19A | c.1157T>C p.M386T | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC25A39 | c.263G>T p.C88F (on ENST00000377095 / NM_001143780.3; = p.C80F on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STK17B | c.928T>C p.S310P | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BZW1 | c.534A>G p.K178= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1941C>T p.H647= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as rs886472452; called by muse, mutect2, varscan2
- TMEM267 | c.645C>G p.V215= | Silent (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
